Surgical pathology report (de-identified scan), TCGA case TCGA-AN-A0XN, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Cureline, specimen TCGA-AN-A0XN-01A (Primary Tumor).

TSS Patient ID:

Case #: DOB: Sex: Female Ethnicity (Race):

Cancer Sample

Diagnosis: Breast Cancer Histological description: Infiltrative ductal carcinoma

Date of Procurement: Anatomic Site: Breast Tumor location: Primary

Tissue Specification: Tumor Specimen Matrix: Tissue Specimen Format: OCT

Container: block Type of Procurement: surgery Grade: 2

T Stage: 2 N Stage: 1 M Stage: 0 Treatment: none

Treatment Details: n/a

Normal Sample

Anatomic Site: Blood Sample Type: Normal Type of Procurement: blood draw

Matrix: Blood Specimen Format: frozen Container: tube

Date of Procurement

ICD-0-3
carcinoma, infiltrating duct, NOS 8500/3
Site: breast, NOS C50.9 lw 10/21/14

lw 10/21/14		

Source: NCI Genomic Data Commons file dc7cba72-d677-4846-a2f0-b7267fd91521 (TCGA-AN-A0XN.4C9C9D24-07E1-47BE-8D34-F94693576BD2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).